Somatic mutation profile of tumor specimen C3N-03233-03 (aliquot CPT0180730006) from CPTAC case C3N-03233, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.2 years (24,895 days).
Specimen C3N-03233-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7923e1e-cbe2-4635-81fb-4cb20f26c7ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03233-71 (Blood Derived Normal), aliquot CPT0180830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97b62962-e516-4376-a085-8474dc646c84

The open-access MAF lists 376 somatic variants for this specimen: 252 protein-altering or splice-affecting, 82 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 209, Silent 82, Nonsense Mutation 23, Intron 14, RNA 10, Splice Region 9, Frame Shift Del 7, 5'UTR 7, 3'UTR 6, Splice Site 4, 3'Flank 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 94/581 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104893619, CM980379, COSV55623679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 43/261 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS9 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.886); catalogued as COSV55787285; called by muse, mutect2, varscan2
- AKAP6 | c.1307A>C p.K436T | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55222823; called by muse, mutect2
- ALLC | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540280415, COSV52998114; called by muse, mutect2, varscan2
- ANKRD30A | c.1000G>A p.G334R (on ENST00000611781; = p.G278R on NM_052997.2) | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as COSV100652654; called by muse, mutect2, varscan2
- ANKRD30A | c.1001G>A p.G334E (on ENST00000611781; = p.G278E on NM_052997.2) | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs1218075934; called by muse, mutect2, varscan2
- AOAH | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV51735544; called by muse, mutect2, varscan2
- ARSI | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 27/155 reads (17%) | catalogued as rs1385841761, COSV60817929; called by muse, mutect2, varscan2
- BARHL1 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as rs774653900; called by muse, mutect2, varscan2
- BSN | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs991962698; called by muse, mutect2, varscan2
- CACNA2D1 | c.2920T>A p.C974S (on ENST00000356253 / NM_001366867.1; = p.C962S on NM_000722.4) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62381920; called by muse, mutect2, varscan2
- CALHM1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs1444728930, COSV61707712; called by muse, mutect2
- CCDC33 | c.1381C>A p.R461S | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs538344642, COSV51503588; called by muse, mutect2, varscan2
- CDH4 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 70/571 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.374); catalogued as rs138803497; called by muse, mutect2, varscan2
- CNTN5 | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54285671; called by muse, mutect2, varscan2
- CRYGD | c.479C>A p.T160K | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100006116; called by muse, mutect2, varscan2
- CSMD3 | c.10589C>A p.A3530E (on ENST00000297405 / NM_001363185.1; = p.A3361E on NM_052900.3) | Missense Mutation (SNP) | VAF 111/406 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV52261015; called by muse, mutect2, varscan2
- DDX59 | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); catalogued as COSV58751878; called by muse, mutect2
- DIO2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV70445903; called by muse, mutect2, varscan2
- DPF2 | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52891414; called by muse, mutect2
- DPPA5 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs1268502178; called by muse, mutect2, varscan2
- EFHB | c.1024A>G p.I342V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs772187940; called by muse, mutect2
- EXD3 | c.297C>T p.H99= | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as rs1045683563; called by muse, varscan2
- FCRL4 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 153/342 reads (45%) | catalogued as COSV54864735; called by muse, mutect2, varscan2
- FFAR1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.753); catalogued as rs754705434; called by muse, mutect2, varscan2
- FGA | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as CM071756; called by muse, mutect2, varscan2
- GBA3 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as COSV72438787; called by muse, mutect2, varscan2
- HNRNPCL2 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 55/440 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV60402700; called by muse, mutect2, varscan2
- HOXB5 | c.14T>A p.F5Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV53312564; called by muse, mutect2, varscan2
- IGKV3-20 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 117/829 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777462919; called by muse, mutect2, varscan2
- IRS2 | c.1237G>C p.G413R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs1321247285; called by muse, mutect2
- KHDRBS2 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV55427288; called by muse, mutect2, varscan2
- LRRK2 | c.2300G>T p.R767L | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as CM1312429, COSV54143918; called by muse, mutect2, varscan2
- MC3R | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV99710668; called by muse, mutect2, varscan2
- MEIS3 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371334677; called by muse, mutect2, varscan2
- MTNR1B | c.568T>A p.C190S | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1206832550; called by muse, mutect2, varscan2
- MYO18B | c.5618G>T p.R1873L | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV59133694; called by muse, mutect2, varscan2
- NELL1 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54273957; called by muse, mutect2, varscan2
- NLRP3 | c.261A>T p.R87S | Missense Mutation (SNP) | VAF 41/436 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.144); catalogued as COSV60232744; called by muse, mutect2
- NPIPB15 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 87/860 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs759126002; called by muse, mutect2, varscan2
- OR2F1 | c.764C>G p.A255G | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as COSV67331958; called by muse, mutect2, varscan2
- OR4D2 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 94/863 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1323238504; called by muse, mutect2, varscan2
- OR4N5 | c.175del p.L59Sfs*33 | Frame Shift Del (DEL) | VAF 25/184 reads (14%) | catalogued as rs759160579; called by mutect2, pindel, varscan2
- OR4S2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 30/232 reads (13%) | catalogued as COSV100412626; called by muse, mutect2, varscan2
- OR5D16 | c.736del p.H246Tfs*2 | Frame Shift Del (DEL) | VAF 25/208 reads (12%) | catalogued as COSV101003871; called by mutect2, pindel, varscan2
- OR6K2 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773736572; called by muse, mutect2, varscan2
- PARVG | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 31/181 reads (17%) | catalogued as COSV63562152, COSV63562889; called by muse, mutect2, varscan2
- PCDHB4 | c.1256C>A p.T419N | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52025188; called by muse, mutect2, varscan2
- PDZRN4 | c.2261G>T p.R754L (on ENST00000402685 / NM_001164595.2; = p.R496L on NM_013377.4) | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.965); catalogued as COSV54211224; called by muse, mutect2
- PEX11B | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1449329894; called by muse, mutect2
- PIK3R5 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52651589; called by muse, mutect2, varscan2
- PMPCB | c.791T>C p.L264S | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1049828788; called by muse, mutect2
- PRKAA2 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as rs1164141817; called by muse, mutect2, varscan2
- PSG1 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as COSV54959904; called by muse, mutect2, varscan2
- PTK2B | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 31/191 reads (16%) | catalogued as COSV100594427; called by muse, mutect2, varscan2
- RAG2 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs759992403; called by muse, mutect2, varscan2
- RANBP2 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 79/654 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51707396; called by muse, mutect2, varscan2
- RASGRP4 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.726); catalogued as rs761249940; called by muse, mutect2
- RGS5 | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as rs866971353, COSV58351377, COSV58354379; called by muse, mutect2, varscan2
- SEMA6C | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1317869581; called by muse, mutect2
- SETD1A | c.2386G>T p.A796S | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs896870277; called by muse, mutect2, varscan2
- SHANK3 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1271671758; called by muse, mutect2
- SIPA1L2 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs775130845; called by muse, mutect2
- SIX3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99578070; called by muse, varscan2
- SLC10A6 | c.326del p.G109Afs*21 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs753933531, COSV56721805; called by mutect2, pindel, varscan2
- SLC29A1 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 91/811 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100505917; called by muse, mutect2, varscan2
- SMG1 | c.9239A>G p.K3080R | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs751816931; called by muse, mutect2, varscan2
- SORL1 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99493285; called by muse, mutect2
- SVEP1 | c.8964G>T p.R2988S | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as rs745621983; called by muse, mutect2
- TEKT1 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV100106536; called by muse, mutect2
- THSD7B | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV99754199; called by muse, mutect2, varscan2
- TLL1 | c.1603C>A p.R535S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV99287784; called by muse, mutect2, varscan2
- TMA16 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV56833742; called by muse, mutect2, varscan2
- TPRX1 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59115052; called by muse, mutect2, varscan2
- TRPM3 | c.2150A>T p.K717M (on ENST00000357533 / NM_001366142.2; = p.K560M on NM_020952.6) | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV62587587; called by muse, mutect2, varscan2
- TTC37 | c.4571G>C p.W1524S | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62454356; called by muse, mutect2, varscan2
- TUBGCP2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs778308160; called by muse, mutect2, varscan2
- TUSC1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 83/864 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV63662116; called by muse, mutect2
- UBA7 | c.1760C>G p.S587* | Nonsense Mutation (SNP) | VAF 8/219 reads (4%) | catalogued as COSV61093507; called by muse, mutect2
- VGLL3 | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV67352447; called by muse, mutect2, varscan2
- ZC3H7A | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs750797587; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2253G>T p.M751I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54296658; called by muse, mutect2, varscan2
- ZNF512B | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs771378885; called by muse, mutect2, varscan2
- ZNF576 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs902772671, COSV100338213; called by muse, mutect2, varscan2
- ZNRF1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 29/537 reads (5%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.885); catalogued as COSV57729665; called by muse, mutect2
- ADAM9 | c.284A>T p.Y95F | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ADCY8 | c.1328T>A p.F443Y | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.2715C>A p.Y905* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3732C>G p.S1244R (on ENST00000370717 / NM_001366005.1; = p.S1188R on NM_012302.4) | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- AKAP6 | c.6050G>T p.G2017V | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- AP1M1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 43/267 reads (16%) | called by muse, mutect2, varscan2
- AP4E1 | c.3071A>G p.N1024S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.089); called by muse, mutect2
- ARNT | c.1294A>T p.K432* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- ATL3 | c.1569G>T p.Q523H | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- ATP12A | c.2619C>A p.G873= | Splice Region (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2535C>A p.D845E (on ENST00000545399 / NM_001256214.2; = p.D832E on NM_152296.5) | Missense Mutation (SNP) | VAF 71/555 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- B3GALNT2 | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- BSN | c.2758G>T p.G920C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- BSPRY | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BTAF1 | c.2164T>A p.S722T | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- BTBD16 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BTN3A3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 24/820 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); called by muse, mutect2
- C4orf54 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C6 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CABS1 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- CCDC136 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CCDC168 | c.19769A>T p.H6590L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CCDC42 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- CD86 | c.49G>T p.A17S (on ENST00000330540 / NM_175862.5; = p.A11S on NM_006889.4) | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDC42BPG | c.3621G>T p.Q1207H | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH10 | c.234A>C p.L78= | Splice Region (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- CDYL | c.767G>T p.S256I (on ENST00000328908 / NM_001368125.1; = p.S202I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- CHMP4C | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLC | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CLEC12B | c.131T>A p.L44Q | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP3 | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 44/438 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- COA5 | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 104/690 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL1A2 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 62/481 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- COL22A1 | c.3771+1G>T p.X1257_splice | Splice Site (SNP) | VAF 18/166 reads (11%) | called by muse, varscan2
- CR1 | c.5065G>T p.A1689S | Missense Mutation (SNP) | VAF 25/381 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.958); called by muse, mutect2
- CXCR4 | c.880C>A p.H294N | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CYLC2 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- DCTN2 | c.856G>A p.V286I (on ENST00000548249 / NM_001261413.2; = p.V291I on NM_006400.4) | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.334); called by muse, mutect2
- DLG5 | c.3403-6C>A | Splice Region (SNP) | VAF 34/191 reads (18%) | called by muse, mutect2, varscan2
- DLGAP1 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DNMT3A | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, varscan2
- DRP2 | c.1054+3A>G | Splice Region (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- EFCAB5 | c.1200G>A p.K400= | Splice Region (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- ENDOU | c.839C>A p.S280* (on ENST00000422538 / NM_001172439.2; = p.S239* on NM_006025.4) | Nonsense Mutation (SNP) | VAF 40/252 reads (16%) | called by muse, mutect2, varscan2
- ENOX1 | c.1223G>T p.C408F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENPEP | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- EPHA5 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERCC2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EWSR1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- F9 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM181A | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2
- FAM98C | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- FANCG | c.77A>C p.Q26P | Missense Mutation (SNP) | VAF 64/846 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FBN2 | c.3184G>T p.G1062W | Missense Mutation (SNP) | VAF 81/530 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FBRSL1 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GAS8 | c.933A>T p.K311N | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- GBA | c.738G>C p.Q246H | Missense Mutation (SNP) | VAF 273/662 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- GLIPR1L2 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLIM4 | c.76T>G p.F26V | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- H2AC11 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 72/568 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HS3ST2 | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 79/518 reads (15%) | called by muse, mutect2, varscan2
- IBSP | c.272A>C p.N91T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); called by muse, varscan2
- IFT80 | c.639+3A>T | Splice Region (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- IGKV2D-30 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 68/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INSL4 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- IPO11 | c.1216A>C p.R406= | Splice Region (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- ITGAL | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ITPR2 | c.5266G>A p.E1756K | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, varscan2
- KCNC4 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KCND1 | c.755C>A p.A252D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KCNH6 | c.589C>A p.R197S | Missense Mutation (SNP) | VAF 101/675 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCTD8 | c.1163C>A p.T388K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KDR | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF1A | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT17P1 | n.1180C>T | Splice Region (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- LAMA2 | c.3625G>T p.G1209C | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LATS2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); called by muse, mutect2
- LCOR | c.523del p.T175Lfs*23 | Frame Shift Del (DEL) | VAF 23/209 reads (11%) | called by mutect2, varscan2
- LHFPL5 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LIG4 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LINGO4 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 205/466 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LMNTD1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); called by muse, mutect2
- LPA | c.4357C>A p.P1453T | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LRRC7 | c.1684C>A p.P562T (on ENST00000651989 / NM_001370785.2; = p.P529T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRC74B | c.1163C>A p.A388E | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- METTL21A | c.231del p.L78Wfs*4 | Frame Shift Del (DEL) | VAF 23/232 reads (10%) | called by mutect2, pindel, varscan2
- MGA | c.5446C>T p.Q1816* (on ENST00000219905 / NM_001164273.1; = p.Q1607* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- MIA3 | c.2395G>T p.V799F | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.641); called by muse, mutect2
- MNDA | c.1033A>T p.T345S | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- MRPL45 | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MSH5 | c.1774G>T p.G592* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- MTNR1B | c.509T>A p.V170E | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MUC17 | c.1409G>T p.S470I | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MYH7 | c.3201G>A p.M1067I | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYO18B | c.113T>G p.I38S | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NBN | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 32/348 reads (9%) | called by muse, mutect2
- NLRP3 | c.951C>A p.C317* | Nonsense Mutation (SNP) | VAF 38/453 reads (8%) | called by muse, mutect2
- NOL6 | c.1000T>A p.W334R | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NSFL1C | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 60/342 reads (18%) | called by muse, varscan2
- NUDT15 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- OR13H1 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- OR1J4 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2
- OR2W3 | c.258T>A p.N86K | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4M1 | c.772T>A p.Y258N | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- OR9Q1 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH11X | c.2159C>T p.T720I | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDH11Y | c.2908C>A p.H970N (on ENST00000400457 / NM_032973.2; = p.H959N on NM_032971.3) | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA1 | c.1988C>G p.A663G | Missense Mutation (SNP) | VAF 53/447 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCDHGB2 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2
- PCMT1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PDCD11 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDP2 | c.68del p.G23Vfs*15 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- PGK2 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PGR | c.2698G>T p.A900S | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PINK1 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 23/435 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2
- PLB1 | c.4026del p.F1343Sfs*109 | Frame Shift Del (DEL) | VAF 33/281 reads (12%) | called by mutect2, pindel, varscan2
- POGLUT2 | c.1400A>C p.Q467P | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- POTED | c.1534-2A>C p.X512_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- PRIM2 | c.595A>T p.K199* | Nonsense Mutation (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- PRX | c.3856G>T p.G1286C | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- RAE1 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RASL10A | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 9/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RPS6KA4 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 100/585 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- RSPO1 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 73/472 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RYR2 | c.7481C>T p.P2494L | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SALL1 | c.2483A>G p.N828S | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SCN10A | c.4784C>T p.T1595I | Missense Mutation (SNP) | VAF 61/522 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- SCN1A | c.3043G>A p.A1015T (on ENST00000303395 / NM_001202435.3; = p.A1004T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SEPTIN12 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SFTPD | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SLC12A6 | c.2903G>T p.R968L (on ENST00000354181 / NM_001365088.1; = p.R917L on NM_005135.2) | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC27A6 | c.1090A>T p.T364S | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SMC5 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); called by muse, mutect2
- SP140L | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2
- SPAM1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 25/195 reads (13%) | called by muse, mutect2, varscan2
- SPDYE1 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 81/554 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- SPTA1 | c.2797G>C p.A933P | Missense Mutation (SNP) | VAF 121/361 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SRMS | c.1331G>C p.R444P | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- STAU2 | c.996A>T p.R332S (on ENST00000524300 / NM_001164380.2; = p.R300S on NM_014393.2) | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- STPG2 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2
- STYXL2 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SYNE2 | c.8875G>T p.A2959S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SYT10 | c.815A>T p.K272M | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TET1 | c.5690A>C p.D1897A | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TEX10 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.34); called by muse, mutect2
- THSD7A | c.4741C>A p.Q1581K | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- THSD7B | c.4365T>A p.D1455E (on ENST00000272643; = p.D1453E on NM_001316349.2) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TINAG | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TMEM74 | c.760A>T p.M254L | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.085); called by muse, mutect2
- TUB | c.43T>A p.F15I | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2
- TUB | c.45T>G p.F15L | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- UQCRC2 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); called by muse, mutect2
- USH2A | c.8944C>G p.H2982D | Missense Mutation (SNP) | VAF 19/571 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.316); called by muse, mutect2
- UTP23 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2
- VSIR | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWA3A | c.3244G>T p.V1082L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- WDR81 | c.3272T>G p.V1091G (on ENST00000409644 / NM_001163809.2; = p.V40G on NM_152348.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- XIRP2 | c.94G>T p.G32C (on ENST00000628543; = p.G207C on NM_152381.6) | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ZAN | c.5921C>A p.A1974D | Missense Mutation (SNP) | VAF 57/433 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ZCCHC8 | c.1745A>T p.E582V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZDHHC13 | c.1731-2A>T p.X577_splice | Splice Site (SNP) | VAF 45/423 reads (11%) | called by muse, mutect2, varscan2
- ZNF157 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ZNF222 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF234 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 33/361 reads (9%) | called by muse, mutect2
- ZNF337 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF423 | c.3776T>G p.V1259G (on ENST00000563137 / NM_001379286.1; = p.V1251G on NM_015069.4) | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); called by muse, mutect2
- ABHD17B | c.729C>G p.G243= | Silent (SNP) | VAF 47/469 reads (10%) | called by muse, mutect2, varscan2
- ACAN | c.4842A>T p.L1614= | Silent (SNP) | VAF 154/562 reads (27%) | called by muse, mutect2, varscan2
- ACRV1 | c.741T>C p.H247= | Silent (SNP) | VAF 35/237 reads (15%) | catalogued as rs769979057; called by muse, mutect2, varscan2
- ADAMTS3 | c.3360A>T p.P1120= | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- AGMO | c.786A>G p.T262= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as rs756927201; called by muse, mutect2, varscan2
- AMTN | c.180C>A p.L60= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- ANO4 | c.144C>A p.T48= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as rs532130054; called by muse, mutect2, varscan2
- ANXA3 | c.255G>T p.V85= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as COSV53716667; called by muse, mutect2, varscan2
- AP4E1 | c.3069A>T p.V1023= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs755016390; called by muse, mutect2
- ARHGAP29 | c.3564A>T p.A1188= | Silent (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- ARNT | c.1296G>A p.K432= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- ATP8A1 | c.3429A>T p.G1143= | Silent (SNP) | VAF 11/260 reads (4%) | catalogued as rs1472181385; called by muse, mutect2
- BICD2 | c.1479C>A p.R493= | Silent (SNP) | VAF 44/400 reads (11%) | called by muse, mutect2, varscan2
- BSPRY | c.156G>T p.R52= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- CAPN13 | c.547C>T p.L183= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as COSV54429900, COSV99700864; called by muse, mutect2, varscan2
- CCT3 | c.1452G>T p.T484= | Silent (SNP) | VAF 25/413 reads (6%) | called by muse, mutect2
- CEP170B | c.1647G>T p.T549= (on ENST00000453495; = p.T478= on NM_015005.3) | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- CROCC2 | c.1621C>A p.R541= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2
- DAGLA | c.2499C>A p.S833= | Silent (SNP) | VAF 48/284 reads (17%) | called by muse, mutect2, varscan2
- ENAM | c.582A>G p.E194= | Silent (SNP) | VAF 16/203 reads (8%) | called by muse, mutect2
- ERCC2 | c.660G>T p.L220= | Silent (SNP) | VAF 44/412 reads (11%) | called by muse, mutect2, varscan2
- EXTL1 | c.1242C>A p.R414= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- FBXO3 | c.825A>G p.P275= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- FGFRL1 | c.636G>T p.R212= | Silent (SNP) | VAF 39/292 reads (13%) | called by muse, mutect2, varscan2
- FOXL1 | c.504G>C p.A168= | Silent (SNP) | VAF 26/212 reads (12%) | called by mutect2, varscan2
- GABRB3 | c.183C>T p.A61= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs774218601, COSV100165139; called by muse, mutect2, varscan2
- GALNT17 | c.1743C>A p.L581= | Silent (SNP) | VAF 52/358 reads (15%) | called by muse, mutect2, varscan2
- GPRIN1 | c.954G>A p.L318= | Silent (SNP) | VAF 30/218 reads (14%) | called by muse, mutect2, varscan2
- HASPIN | c.1419C>A p.V473= | Silent (SNP) | VAF 39/256 reads (15%) | called by muse, mutect2, varscan2
- HMCN1 | c.9294G>C p.R3098= | Silent (SNP) | VAF 26/598 reads (4%) | catalogued as rs1350209898; called by muse, mutect2
- HMCN2 | c.11919C>A p.I3973= | Silent (SNP) | VAF 32/246 reads (13%) | called by muse, mutect2, varscan2
- HPS4 | c.939C>T p.S313= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs375673570; called by muse, mutect2, varscan2
- HTRA3 | c.744C>T p.A248= | Silent (SNP) | VAF 52/385 reads (14%) | catalogued as rs755599433; called by muse, mutect2, varscan2
- IGLC3 | c.306T>A p.P102= | Silent (SNP) | VAF 43/403 reads (11%) | called by muse, mutect2, varscan2
- ITGAE | c.378T>C p.C126= | Silent (SNP) | VAF 17/200 reads (9%) | catalogued as rs1433784411; called by muse, mutect2
- KCNH2 | c.2958C>T p.P986= | Silent (SNP) | VAF 54/417 reads (13%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2571G>T p.G857= | Silent (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- KCP | c.3030C>T p.P1010= (on ENST00000620378; = p.P1070= on NM_001366122.1) | Silent (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2, varscan2
- KIAA1549L | c.2214G>A p.L738= (on ENST00000321505; = p.L1035= on NM_012194.3) | Silent (SNP) | VAF 56/440 reads (13%) | called by muse, varscan2
- KPNB1 | c.1359A>G p.L453= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs956545377; called by muse, mutect2, varscan2
- LY6G5B | c.270A>G p.A90= | Silent (SNP) | VAF 12/283 reads (4%) | called by muse, mutect2
- LYPD5 | c.294G>C p.S98= (on ENST00000377950 / NM_001031749.3; = p.S55= on NM_182573.2) | Silent (SNP) | VAF 23/438 reads (5%) | called by muse, mutect2
- MAGEL2 | c.2511C>A p.V837= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as COSV58568010; called by muse, mutect2, varscan2
- MICAL3 | c.1632C>A p.T544= | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- MOCOS | c.825G>T p.L275= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs1031882889; called by muse, mutect2, varscan2
- MTNR1A | c.735C>A p.V245= | Silent (SNP) | VAF 12/281 reads (4%) | catalogued as rs1326748884; called by muse, mutect2
- MUC13 | c.240C>A p.S80= | Silent (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- MYH1 | c.5448C>A p.I1816= | Silent (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- MYO5B | c.1203C>A p.R401= | Silent (SNP) | VAF 33/776 reads (4%) | called by muse, mutect2
- NBAS | c.1203G>T p.V401= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV55736762; called by muse, mutect2, varscan2
- NCKAP1L | c.3300C>T p.T1100= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV53204225; called by muse, mutect2, varscan2
- NRIP1 | c.1614T>A p.S538= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- NTNG2 | c.936C>A p.T312= | Silent (SNP) | VAF 43/308 reads (14%) | called by muse, mutect2, varscan2
- NUDT14 | c.12C>T p.I4= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs1283638601; called by muse, mutect2, varscan2
- PANK4 | c.1497G>A p.G499= | Silent (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.2862G>A p.G954= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- PEBP1 | c.210C>T p.D70= | Silent (SNP) | VAF 33/294 reads (11%) | called by muse, mutect2, varscan2
- PIK3C2A | c.1341A>G p.V447= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- PMS1 | c.1722C>A p.P574= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as rs1468732089; called by muse, mutect2
- POM121L12 | c.394C>A p.R132= | Silent (SNP) | VAF 109/539 reads (20%) | called by muse, mutect2, varscan2
- PPP1R12B | c.600C>G p.R200= | Silent (SNP) | VAF 80/308 reads (26%) | called by muse, mutect2, varscan2
- PRELP | c.297C>T p.V99= | Silent (SNP) | VAF 53/371 reads (14%) | called by muse, mutect2, varscan2
- PRKDC | c.3783G>T p.L1261= | Silent (SNP) | VAF 34/280 reads (12%) | called by muse, mutect2, varscan2
- PSMD3 | c.63A>T p.G21= | Silent (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- PTP4A1 | c.474G>A p.L158= | Silent (SNP) | VAF 28/225 reads (12%) | called by muse, mutect2, varscan2
- RBM24 | c.609A>T p.A203= (on ENST00000379052 / NM_001143942.2; = p.A158= on NM_153020.2) | Silent (SNP) | VAF 40/217 reads (18%) | called by muse, mutect2, varscan2
- RRN3 | c.1914G>T p.V638= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- SCAMP3 | c.765A>T p.P255= | Silent (SNP) | VAF 57/269 reads (21%) | called by muse, mutect2, varscan2
- SLC11A1 | c.465C>T p.G155= | Silent (SNP) | VAF 42/322 reads (13%) | called by muse, mutect2, varscan2
- SLC1A5 | c.309C>T p.I103= | Silent (SNP) | VAF 36/810 reads (4%) | called by muse, mutect2
- SLC6A11 | c.6G>T p.T2= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- SLC7A7 | c.366C>T p.T122= | Silent (SNP) | VAF 48/377 reads (13%) | catalogued as rs773372874; called by muse, mutect2, varscan2
- SOS2 | c.2289C>T p.I763= | Silent (SNP) | VAF 33/265 reads (12%) | called by muse, mutect2, varscan2
- SYNE1 | c.10167C>T p.S3389= (on ENST00000367255 / NM_182961.4; = p.S3396= on NM_033071.3) | Silent (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- TICRR | c.588A>G p.R196= | Silent (SNP) | VAF 56/155 reads (36%) | called by muse, mutect2, varscan2
- TMC2 | c.2025G>A p.V675= | Silent (SNP) | VAF 82/523 reads (16%) | called by muse, mutect2, varscan2
- TMC3 | c.1836A>T p.R612= | Silent (SNP) | VAF 45/200 reads (23%) | called by muse, mutect2, varscan2
- TRPA1 | c.501A>T p.T167= | Silent (SNP) | VAF 25/395 reads (6%) | called by muse, mutect2
- VEGFC | c.603C>T p.I201= | Silent (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2, varscan2
- XIRP2 | c.6825G>C p.L2275= (on ENST00000628543; = p.L2450= on NM_152381.6) | Silent (SNP) | VAF 31/188 reads (16%) | called by muse, mutect2, varscan2
- ZNF341 | c.654G>A p.V218= | Silent (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
- ZSCAN18 | c.1224C>T p.S408= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs1331705528, COSV53731213; called by muse, mutect2
- ABCC13 | n.261G>C | RNA (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- AC022415.2 | c.*2030G>C | 3'UTR (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- AC132807.2 | n.274C>G | RNA (SNP) | VAF 25/224 reads (11%) | called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551102 T>C | 5'Flank (SNP) | VAF 40/306 reads (13%) | called by muse, varscan2
- ANKRD11 | c.745-601G>A | Intron (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- APOBEC3F | c.172-832A>T | Intron (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- BTN2A3P | n.1149G>T | RNA (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- C10orf90 | c.-3G>T | 5'UTR (SNP) | VAF 25/361 reads (7%) | called by muse, mutect2
- COL25A1 | c.1845+10C>A | Intron (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- COL2A1 | c.-31G>T | 5'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- COL4A2 | c.1433-585G>A | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- DNM1P46 | n.345A>G | RNA (SNP) | VAF 85/341 reads (25%) | catalogued as rs768001086; called by muse, mutect2, varscan2
- DNMT3A | c.448+32T>C | Intron (SNP) | VAF 44/297 reads (15%) | called by muse, varscan2
- EVI5 | c.1344+3146C>T | Intron (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
- EVL | c.352+12087G>T | Intron (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- FAM205BP | n.1577C>A | RNA (SNP) | VAF 34/438 reads (8%) | called by muse, mutect2
- GLRX5 | c.-27G>T | 5'UTR (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- GRM1 | c.-15C>A | 5'UTR (SNP) | VAF 38/357 reads (11%) | called by muse, mutect2, varscan2
- HMCES | c.-18G>A | 5'UTR (SNP) | VAF 14/289 reads (5%) | catalogued as COSV100136028; called by muse, mutect2
- HRH2 | chr5:175685514 C>A | 3'Flank (SNP) | VAF 20/133 reads (15%) | catalogued as COSV51573300; called by muse, mutect2, varscan2
- HSP90B1 | c.152+94A>G | Intron (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- HSPA7 | n.291G>A | RNA (SNP) | VAF 83/968 reads (9%) | catalogued as rs1308376400; called by muse, mutect2
- IL17A | c.-21A>T | 5'UTR (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1596C>A | Intron (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049820 C>A | 3'Flank (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- KRT8P11 | n.202T>C | RNA (SNP) | VAF 55/368 reads (15%) | called by muse, mutect2, varscan2
- LMNA | c.*27G>T | 3'UTR (SNP) | VAF 43/380 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+966A>T | Intron (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- MIR520F | n.9T>A | RNA (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671064 A>G | 3'Flank (SNP) | VAF 54/269 reads (20%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.483dup | RNA (INS) | VAF 43/294 reads (15%) | called by mutect2, pindel, varscan2
- PCDHA10 | c.2388+4629G>A | Intron (SNP) | VAF 97/645 reads (15%) | called by muse, mutect2, varscan2
- PRSS37 | c.430+230C>A | Intron (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- SHISA9 | c.-55C>A | 5'UTR (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- SUMF1 | c.*19C>T | 3'UTR (SNP) | VAF 29/237 reads (12%) | called by muse, mutect2, varscan2
- TCF7 | c.*10G>A | 3'UTR (SNP) | VAF 42/244 reads (17%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*988A>T | 3'UTR (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- TSBP1-AS1 | n.374G>T | RNA (SNP) | VAF 22/189 reads (12%) | called by muse, mutect2, varscan2
- TSPY10 | c.*29T>C | 3'UTR (SNP) | VAF 14/554 reads (3%) | called by muse, mutect2
- TTYH1 | c.126+1183C>T | Intron (SNP) | VAF 44/349 reads (13%) | called by muse, mutect2, varscan2
- TVP23C | chr17:15566152 G>T | 5'Flank (SNP) | VAF 23/192 reads (12%) | catalogued as rs763319073; called by muse, mutect2, varscan2
- ZNF787 | c.79+32C>T | Intron (SNP) | VAF 13/107 reads (12%) | catalogued as rs747944867; called by muse, mutect2, varscan2
